Somatic mutation profile of tumor specimen TARGET-40-PAMHLF-01A (aliquot TARGET-40-PAMHLF-01A-02D) from TARGET case TARGET-40-PAMHLF, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 8.9 years (3,233 days).
Specimen TARGET-40-PAMHLF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 78147e26-1842-41a2-91fb-94731b3fba33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-PAMHLF-10A (Blood Derived Normal), aliquot TARGET-40-PAMHLF-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c62c2f69-f3cf-4e63-b367-867eb196d8a0

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 2 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Intron 3, Nonsense Mutation 2, Silent 2, 5'UTR 1, 3'UTR 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.659A>G p.Y220C | Missense Mutation (SNP) | VAF 10/12 reads (83%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912666, CM015378, CM951227, COSV52661282, COSV52677517; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- FKBP9 | c.1034G>A p.G345E | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99640209; called by muse, mutect2, varscan2
- SCO1 | c.100G>A p.E34K | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0); catalogued as rs776887702, COSV55135166; called by muse, varscan2
- SLC8A3 | c.1291G>T p.V431L | Missense Mutation (SNP) | VAF 29/256 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.156); catalogued as COSV63521722; called by muse, mutect2, varscan2
- CALM1 | c.440C>T p.T147I | Missense Mutation (SNP) | VAF 25/50 reads (50%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); called by muse, mutect2, varscan2
- CAMSAP1 | c.2959G>A p.A987T | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (0.63); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD1L | c.523G>A p.E175K | Missense Mutation (SNP) | VAF 44/472 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- INSRR | c.1747G>T p.E583* | Nonsense Mutation (SNP) | VAF 18/56 reads (32%) | called by muse, mutect2, varscan2
- KLHL35 | c.1096A>T p.M366L | Missense Mutation (SNP) | VAF 34/103 reads (33%) | SIFT tolerated (0.8); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- MUC16 | c.246G>T p.M82I | Missense Mutation (SNP) | VAF 47/276 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- PCLO | c.6424G>T p.E2142* | Nonsense Mutation (SNP) | VAF 50/187 reads (27%) | called by muse, mutect2, varscan2
- RIOK3 | c.1254+2T>C p.X418_splice | Splice Site (SNP) | VAF 25/76 reads (33%) | called by muse, mutect2, varscan2
- RPA4 | c.73C>A p.L25M | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.133); called by muse, mutect2
- RSBN1L | c.2059C>T p.H687Y | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZDBF2 | c.2069T>C p.V690A | Missense Mutation (SNP) | VAF 38/225 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ZNF433 | c.964C>T p.P322S | Missense Mutation (SNP) | VAF 15/203 reads (7%) | SIFT tolerated (0.48); PolyPhen benign (0.003); called by muse, mutect2
- ZNF816 | c.1009G>A p.G337R | Missense Mutation (SNP) | VAF 10/183 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); called by muse, mutect2
- INPP5D | c.1194G>A p.Q398= (on ENST00000445964 / NM_001017915.3; = p.Q397= on NM_005541.5) | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as rs1168506572; called by muse, mutect2, varscan2
- TMEM266 | c.726C>T p.D242= | Silent (SNP) | VAF 28/206 reads (14%) | catalogued as rs747155045, COSV66381207; called by muse, mutect2, varscan2
- CCDC39 | c.-88C>T | 5'UTR (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- CD6 | c.1583-27G>A | Intron (SNP) | VAF 6/48 reads (13%) | catalogued as rs755574466, COSV57837213; called by mutect2, varscan2
- GRM6 | c.*85C>T | 3'UTR (SNP) | VAF 18/28 reads (64%) | called by muse, mutect2
- PCK2 | c.1234+182G>A | Intron (SNP) | VAF 16/36 reads (44%) | catalogued as rs991927367; called by muse, mutect2, varscan2
- PRPF3 | c.277-30C>T | Intron (SNP) | VAF 39/214 reads (18%) | called by muse, mutect2, varscan2
